Somatic mutation profile of tumor specimen C3N-01416-03 (aliquot CPT0105710009) from CPTAC case C3N-01416, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.2 years (24,540 days).
Specimen C3N-01416-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ceb966d-798d-457a-8665-78dc24b03189.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01416-31 (Blood Derived Normal), aliquot CPT0108160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/212668ed-3ba6-4d2f-b0e6-4c5d4b4a8b1b

The open-access MAF lists 93 somatic variants for this specimen: 58 protein-altering or splice-affecting, 24 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 24, Nonsense Mutation 8, Intron 7, RNA 3, Frame Shift Del 1, In Frame Del 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 77/440 reads (18%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- RB1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | catalogued as rs121913301, CM951105, CM961226, COSV57296833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 38/169 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377767347, CM004254, CM100519, COSV61684056, COSV61686014, COSV61689167; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS4 | c.1648C>A p.P550T | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99058170; called by muse, mutect2
- C10orf71 | c.3389C>T p.S1130L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1471758251, COSV60506084; called by muse, mutect2
- COPB1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.216); catalogued as COSV51448962; called by muse, mutect2
- DCTN1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1443384895; ClinVar: uncertain significance; called by muse, mutect2
- ERBIN | c.2759A>G p.Y920C | Missense Mutation (SNP) | VAF 40/215 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs374278956; called by muse, mutect2, varscan2
- GRM1 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 64/262 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1562414099, COSV51123819, COSV51138034; called by muse, mutect2, varscan2
- HECW1 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.391); catalogued as rs762002584, COSV67826169, COSV67842008; called by muse, mutect2, varscan2
- LRRC7 | c.2383C>T p.R795W (on ENST00000651989 / NM_001370785.2; = p.R762W on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs766749937; called by muse, mutect2, varscan2
- LRRIQ3 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as rs1333283471; called by muse, varscan2
- MUC17 | c.12301C>T p.R4101W | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs368040615, COSV60280196; called by muse, mutect2
- OMA1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 11/150 reads (7%) | catalogued as rs775636632; called by muse, mutect2
- PRPF8 | c.6469G>C p.V2157L | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.172); catalogued as rs750741891, COSV100025383; called by muse, mutect2, varscan2
- ROS1 | c.2111T>A p.I704K | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100877912; called by muse, mutect2, varscan2
- SELENOI | c.1023C>A p.Y341* | Nonsense Mutation (SNP) | VAF 21/144 reads (15%) | catalogued as COSV99564236; called by muse, mutect2, varscan2
- SLC35G3 | c.995G>A p.R332K | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1555582813; called by muse, mutect2, varscan2
- TRMT1L | c.1407G>C p.L469F | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV99055603; called by muse, mutect2
- TUBGCP3 | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs778702048; called by muse, mutect2, varscan2
- WDR72 | c.661T>C p.C221R | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64741655; called by muse, mutect2, varscan2
- ZAP70 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.076); catalogued as COSV53852946; called by muse, mutect2
- ZFP57 | c.1136C>G p.S379* | Nonsense Mutation (SNP) | VAF 64/556 reads (12%) | catalogued as COSV100971998; called by muse, varscan2
- ZNF804A | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100166602, COSV56468179; called by muse, mutect2
- ZPBP | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs776265657, COSV50423164; called by muse, mutect2, varscan2
- ANTKMT | c.268-2A>T p.X90_splice | Splice Site (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- BAK1 | c.271T>C p.S91P | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1D | c.2205_2212del p.F736Wfs*2 (on ENST00000350061 / NM_001128840.3; = p.F756Wfs*2 on NM_000720.4) | Frame Shift Del (DEL) | VAF 28/330 reads (8%) | called by mutect2, pindel
- CACNA1H | c.1956C>G p.N652K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- CEP250 | c.2678A>T p.E893V | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CRYBG1 | c.3601A>T p.K1201* | Nonsense Mutation (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- DOCK10 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- DST | c.890G>C p.R297T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- FAM83G | c.2093T>G p.F698C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- FCHSD1 | c.118A>G p.R40G | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCSK | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GID8 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 44/252 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HECTD2 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIFAP3 | c.2195G>A p.G732E | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.306); called by muse, mutect2
- KRT1 | c.918C>A p.D306E | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- LOXL3 | c.647T>A p.M216K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MAPK11 | c.498C>T p.I166= | Splice Region (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- MXRA5 | c.7789G>A p.A2597T | Missense Mutation (SNP) | VAF 70/432 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NELFCD | c.118G>A p.E40K (on ENST00000602795; = p.E22K on NM_198976.4) | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- OR3A3 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCDHA3 | c.1096A>T p.S366C | Missense Mutation (SNP) | VAF 62/341 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PTGES3L-AARSD1 | c.941dup p.S315Efs*7 (on ENST00000421990 / NM_001136042.2; = p.S297Efs*7 on NM_025267.3) | Frame Shift Ins (INS) | VAF 21/125 reads (17%) | called by mutect2, pindel, varscan2
- PTPN22 | c.1478C>G p.S493C (on ENST00000359785 / NM_001193431.2; = p.S438C on NM_012411.5) | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- RAB40AL | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 41/278 reads (15%) | called by muse, mutect2, varscan2
- RHPN2 | c.553T>C p.F185L | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNF216 | c.1348G>T p.E450* (on ENST00000425013 / NM_207116.3; = p.E507* on NM_207111.4) | Nonsense Mutation (SNP) | VAF 25/133 reads (19%) | called by muse, mutect2, varscan2
- RYR1 | c.5377G>C p.E1793Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- SLC35G3 | c.996G>C p.R332S | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- SORL1 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TAF7 | c.16G>C p.D6H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); called by muse, mutect2
- TP53BP1 | c.5714C>G p.S1905* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2
- ZNF7 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF91 | c.1054T>A p.C352S | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY3 | c.1705C>T p.L569= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV99568247; called by muse, mutect2, varscan2
- ATP2A3 | c.3087G>C p.V1029= (on ENST00000352011 / NM_174955.3; = p.*1000Sext*42 on NM_005173.4) | Silent (SNP) | VAF 13/228 reads (6%) | called by muse, mutect2
- DISC1 | c.2564G>A p.*855= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- KCNK2 | c.564C>G p.L188= (on ENST00000444842 / NM_001017425.3; = p.L173= on NM_014217.4) | Silent (SNP) | VAF 10/257 reads (4%) | called by muse, mutect2
- KIRREL1 | c.336C>T p.A112= | Silent (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- KRT26 | c.858A>G p.Q286= | Silent (SNP) | VAF 23/166 reads (14%) | catalogued as rs1304317045; called by muse, mutect2, varscan2
- LRRC2 | c.396G>A p.L132= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs185194986; called by muse, mutect2, varscan2
- MEN1 | c.1824C>G p.L608= | Silent (SNP) | VAF 9/296 reads (3%) | catalogued as COSV53641457; called by muse, mutect2
- MMP2 | c.1014C>T p.S338= | Silent (SNP) | VAF 44/368 reads (12%) | catalogued as COSV99528220; called by muse, mutect2, varscan2
- MYOF | c.2718A>G p.E906= | Silent (SNP) | VAF 13/89 reads (15%) | called by muse, mutect2, varscan2
- PABPC5 | c.570C>T p.V190= | Silent (SNP) | VAF 34/886 reads (4%) | called by muse, mutect2
- PDIA3 | c.438G>A p.K146= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.1392C>T p.G464= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as rs758547297, COSV70819940; called by muse, mutect2
- PRSS48 | c.354G>A p.L118= | Silent (SNP) | VAF 20/287 reads (7%) | called by muse, mutect2
- RASSF9 | c.819G>T p.L273= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as COSV63433403; called by muse, mutect2
- SP1 | c.888A>G p.S296= (on ENST00000327443 / NM_138473.3; = p.S289= on NM_003109.1) | Silent (SNP) | VAF 55/270 reads (20%) | called by muse, mutect2, varscan2
- SPTBN4 | c.5163G>A p.V1721= | Silent (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- STK31 | c.2139C>T p.L713= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- TMEM74B | c.453G>A p.P151= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as rs145626707; called by muse, mutect2
- TTN | c.81153A>G p.K27051= (on ENST00000591111; = p.K19627= on NM_003319.4) | Silent (SNP) | VAF 36/257 reads (14%) | called by muse, mutect2, varscan2
- URGCP | c.813T>C p.S271= (on ENST00000453200 / NM_001077663.3; = p.S262= on NM_017920.4) | Silent (SNP) | VAF 43/383 reads (11%) | called by mutect2, varscan2
- ZDHHC11B | c.66G>A p.L22= | Silent (SNP) | VAF 41/209 reads (20%) | catalogued as rs773109961; called by muse, mutect2, varscan2
- ZIC1 | c.477C>G p.V159= | Silent (SNP) | VAF 7/193 reads (4%) | called by muse, mutect2
- ZNF462 | c.684C>T p.I228= | Silent (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2744T>A | RNA (SNP) | VAF 14/126 reads (11%) | called by muse, varscan2
- AC024940.1 | n.2742T>A | RNA (SNP) | VAF 13/126 reads (10%) | called by muse, varscan2
- CBFA2T2 | c.719+577G>C | Intron (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- CD84 | c.778+28C>T | Intron (SNP) | VAF 22/208 reads (11%) | catalogued as rs748542662; called by muse, mutect2, varscan2
- GPS1 | c.33+459G>C | Intron (SNP) | VAF 5/144 reads (3%) | called by muse, mutect2
- LCP2 | c.1323+774C>T | Intron (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- LINC02253 | n.575-1368C>G | Intron (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- OR7E5P | n.653G>A | RNA (SNP) | VAF 15/163 reads (9%) | catalogued as rs768970957; called by muse, mutect2
- SHMT2 | c.-1G>A | 5'UTR (SNP) | VAF 6/140 reads (4%) | catalogued as COSV100196942; called by muse, mutect2
- SOX6 | c.445+38dup | Intron (INS) | VAF 30/167 reads (18%) | called by mutect2, pindel, varscan2
- ZMYND8 | c.26-8463_26-8443del | Intron (DEL) | VAF 10/102 reads (10%) | called by mutect2, pindel
